Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7397, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7397-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) NECK, LEVEL 3, RIGHT, EXCISION: METASTATIC SQUAMOUS CELL CARCINOMA IN TWO LYMPH NODES (2/7).
- 2) NECK, LEVEL 2, SITE UNSPECIFIED, EXCISION: METASTATIC SQUAMOUS CELL CARCINOMA IN ONE LYMPH NODE (1/4).
- 3) NECK, LEVEL 2, EXCISION: METASTATIC SQUAMOUS CELL CARCINOMA IN THREE LYMPH NODES (3/4).
- 4) LYMPH NODE, SUBMENTAL, EXCISION: NO TUMOR IDENTIFIED IN FOUR LYMPH NODES (0/4).
- 5) LYMPH NODE, LEVEL 1, EXCISION: METASTATIC SQUAMOUS CELL CARCINOMA IN TWO LYMPH NODES (2/6).
- 6) TONGUE, RIGHT, HEMIGLOSSECTOMY: INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (4.5 CM); MARGINS NEGATIVE FOR TUMOR (SEE SYNOPTIC REPORT).
- 7) LYMPH NODE, LEVEL 3, 4, EXCISION: NO TUMOR IDENTIFIED IN FIVE LYMPH NODES (0/5).
- 8) LYMPH NODE, LEVEL 2B, EXCISION: NO TUMOR IDENTIFIED IN THREE LYMPH NODES (0/3).
- 9) LYMPH NODE, ANTERIOR LEVEL 3, EXCISION: NO TUMOR IDENTIFIED (0/1).

Upper Aerodigestive Tract-including Minor Salivary Glands, Lip, Oral cavity, Nasal Cavity, Paranasal Sinuses, Oropharynx, Nasopharynx, and Hypopharynx

Summary of Findings:

Specimen Type: hemiglossectomy

Tumor Site: tongue

Tumor Size: 4.5 cm in greatest dimension

Laterality:

X Right

[page 2 of 4]
Margins (select all that apply)

X Margin uninvolved by invasive carcinoma (0.4 cm away from deep margin)

Histologic Type: squamous cell carcinoma

Histologic Grade: moderately differentiated

Pathologic Staging (pTMN)

Primary tumor (pT): T3

Regional Lymph Nodes (pN): N2b

Number examined: 34

Numbered involved: 8

Extracapsular extension: yes

Perineural invasion: (Select one)

X___ No

Bony/Cartilage Invasion: (Select one)

X Not evaluable

Lymph-Vascular invasion: (Select one)

X No

HPV testing ordered: NO (performed on oral cavity and oropharyngeal squamous cell carcinomas)

Electronically Signed Out by [REDACTED].

[REDACTED])

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) right neck level 3 for frozen section;

2) level 2 node; 3) level 2; 4) submental

lymph node; 5) level 1; 6) right

hemiglossectomy; 7) level 3,4; 8) level

2B; 9) anterior level 3

GROSS DESCRIPTION:

1) SOURCE: Right Neck Level 3

The specimen consists of a single portion of yellow to red fatty soft tissue measuring 3.8 x 3.7 x 0.6 cm. Palpating the tissue reveals a large lymph node measuring 1.8 x 0.9 x 0.6 cm. There is a second lymph node measuring 1.7 x 0.6 x 0.6 cm. Of the remaining fatty tissue, there are three probable lymph nodes which range in greatest dimension from 0.4 to 0.6 cm. Serially sectioning the specimen reveals three additional possible

[page 3 of 4]
lymph nodes all less than 0.4 cm in greatest dimension. The specimen is representatively submitted as follows:

Summary of sections:

1AFSC, 1/1

1B, is the remaining portion of the node that had been frozen, 2/1;

1C, the second largest node bisected, 2/1;

1D, three bisected nodes which have been differentially inked, 3/1

1E, four possible nodes which have been differentially inked, 3/1.

2) SOURCE: Level 2 Node

Received fresh in a container labeled with the patient's name and "level 2 node" is a 3.0 x 2.0 x 1.5 cm piece of fibroadipose tissue from which four lymph nodes are dissected that range from 1.0 to 1.5 cm. The lymph nodes are entirely submitted.

Summary of sections: 2A, 4/1.

3) SOURCE: Level 2

Received fresh in a container labeled with the patient's name and "level 2" is a 6.0 x 2.0 x 1.0 cm piece of fibroadipose tissue. Four lymph nodes are dissected.

Summary of sections: 3A, four lymph nodes, 4/1.

4) SOURCE: Submental Lymph Node

Received fresh in a container labeled with the patient's name and "submental lymph node" is a 4.0 x 3.0 x 1.0 cm piece of fibroadipose tissue. Four lymph nodes are dissected.

Summary of sections: 4A, four lymph nodes, 4/1.

5) SOURCE: Level 1

Received fresh in a container labeled with the patient's name and "level 1" is an 8.0 x 4.0 x 3.0 cm piece of fibroadipose tissue with attached salivary gland and skeletal muscle. Multiple lymph nodes are dissected from the specimen that range from 0.5 to 2.0 cm in their greatest extent. The largest lymph node is rubbery, firm, and has a white, friable and necrotic cut surface. An attached 3.5 x 3.5 x 3.0 cm salivary gland is serially sectioned and is grossly unremarkable. The lymph nodes are entirely submitted. Representative sections of the specimen are submitted.

Summary of sections: 5A, five lymph nodes, 5/1;

5B, large suspicious lymph nodes, 2/1;

5C, sections of salivary gland, 2/1;

6) SOURCE: Right Hemi-glossectomy

Received fresh in a container labeled with the patient's name and "right hemiglossectomy" is a 7.5 x 6.5 x 3.0 cm hemiglossectomy specimen that harbors a 4.5 x 3.5 cm ulcer on its lateral mucosal surface. This lesion is 1.6 cm away from the anterior margin, 2.3 cm away from the medial margin, 2.0 cm away from the posterior margin, and 3.5 cm away from the lateral buccal mucosal margin and 2.2 cm away from the deep, floor of mouth margin. The specimen is inked as follows: 6A, anterior margin, blue, lateral margin

[page 4 of 4]
yellow, medial margin green, and floor of mouth margin black. The specimen is serially sectioned to reveal the lesion to extend by 2.3 cm into the tongue and has a solid, white, and fibrotic firm cut surface.

Summary of sections: 6A, anterior margin to mass, 2/1;

6B, representative section of mass to lateral, buccal mucosa margin, 1/1;

6C, representative section of posterior margin, 1/1;

6D, representative section of medial margin to tumor, 1/1;

6E-6H, representative sections of mass, 6E-6F, 1/1; 6G-6H, 2/1 each.

7) SOURCE: Levels 3, 4

Received fresh in a container labeled with the patient's name and "level 3 and 4" is a 6.0 x 5.0 x 1.0 cm piece of fibroadipose tissue from which six lymph nodes are dissected.

Summary of sections: 7A, 6/1.

8) SOURCE: Level 2B

Received fresh in a container labeled with the patient's name and "level 2B" is a 3.5 x 3.0 x 1.0 cm piece of fibroadipose tissue. Two grossly identifiable lymph node candidates are dissected. Representative sections of the specimen are submitted.

Summary of sections: 8A, are two grossly identifiable lymph node candidates, 2/1;

8B, representative sections of remaining adipose tissue, 1/1.

9) SOURCE: Anterior Level 3

Received fresh in a container labeled with the patient's name and "anterior level 3" is a 6.0 x 4.5 x 1.0 cm piece of fibroadipose tissue from which one grossly identifiable lymph node is dissected.

Representative sections of the specimen are submitted.

Summary of sections: 9A, one grossly identifiable lymph node, 1/1;

9B-9C, representative sections of adipose tissue, 1/1 each;

Dictated by [REDACTED] 1

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Right Neck Level 3

FROZEN SECTION DIAGNOSIS: POSITIVE FOR METASTATIC SQUAMOUS CELL CARCINOMA.
CS/EM

Electronically signed by: [REDACTED] Attending Pathologist

Source: NCI Genomic Data Commons file 37264844-09a8-4c20-bc7a-a9805d166d8f (TCGA-CR-7397.C36AA70D-9060-4838-B42A-91DF21A8F34A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).